Somatic mutation profile of tumor specimen ALCH-B4C7-TTP1-A (aliquot ALCH-B4C7-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4C7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.4 years (27,529 days).
Specimen ALCH-B4C7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e78beaa3-3d76-4eee-afec-45c6b46dbe63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4C7-NB1-A (Blood Derived Normal), aliquot ALCH-B4C7-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/841af051-0b1f-4b1e-a796-c3594fd8ef31

The open-access MAF lists 461 somatic variants for this specimen: 311 protein-altering or splice-affecting, 91 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 264, Silent 91, Intron 30, Nonsense Mutation 21, Frame Shift Del 11, 5'UTR 9, 3'UTR 7, Splice Region 6, RNA 6, Splice Site 6, 3'Flank 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.8962dup p.D2988Gfs*2 | Frame Shift Ins (INS) | VAF 140/352 reads (40%) | catalogued as rs771806027, CI084262; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ABCA3 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100068175; called by muse, mutect2, varscan2
- AC008676.3 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as COSV56637006; called by muse, mutect2, varscan2
- ACKR1 | c.24G>A p.A8= | Splice Region (SNP) | VAF 5/25 reads (20%) | catalogued as rs376855885; called by muse, mutect2, varscan2
- ADAM23 | c.2359G>T p.G787C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs376215273; called by muse, mutect2, varscan2
- AKTIP | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs1394013364, COSV100043254; called by muse, mutect2, varscan2
- ANO4 | c.1073C>G p.T358S (on ENST00000392977 / NM_001286615.2; = p.T323S on NM_178826.4) | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1249635086; called by muse, mutect2, varscan2
- ARMCX1 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.597); catalogued as COSV65705122; called by muse, mutect2, varscan2
- ATF7IP | c.1991A>G p.H664R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs759330230; called by muse, mutect2
- C10orf71 | c.2932C>A p.P978T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1225285076; called by muse, mutect2, varscan2
- CD1E | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 23/277 reads (8%) | catalogued as COSV100936908; called by muse, mutect2
- CDH18 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 143/390 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV56975147, COSV99931852; called by muse, mutect2, varscan2
- CEP83 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs968094726; called by muse, mutect2, varscan2
- CFAP53 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs1056143543; called by muse, mutect2, varscan2
- CFAP57 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as rs373115482; called by muse, mutect2, varscan2
- CNGB1 | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as COSV51905504; called by muse, mutect2, varscan2
- COL20A1 | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761888559; called by muse, mutect2, varscan2
- COL22A1 | c.2611G>A p.G871R | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57322681; called by muse, mutect2, varscan2
- COL22A1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs138591562; called by muse, mutect2
- CREB3L3 | c.900G>T p.L300F | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99314626; called by mutect2, varscan2
- CSMD3 | c.1537G>A p.D513N (on ENST00000297405 / NM_001363185.1; = p.D409N on NM_052900.3) | Missense Mutation (SNP) | VAF 127/545 reads (23%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.84); catalogued as COSV99826252; called by muse, mutect2, varscan2
- CST9 | c.443C>A p.A148E | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as COSV100980453; called by muse, mutect2, varscan2
- CYLD | c.327G>T p.R109S | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100282209; called by muse, mutect2, varscan2
- DISP2 | c.3514C>T p.R1172W | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1051995309; called by muse, mutect2, varscan2
- DMTN | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56112419; called by muse, mutect2
- DNAJC3 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as rs776226684, COSV65132706; called by muse, mutect2, varscan2
- DNM1 | c.1564C>A p.R522S | Missense Mutation (SNP) | VAF 115/185 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV100360433, COSV57850426; called by muse, mutect2, varscan2
- DOCK6 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV53919855; called by muse, mutect2, varscan2
- DSC2 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV51864031; called by muse, mutect2, varscan2
- DZIP3 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV64312509; called by muse, mutect2, varscan2
- EFTUD2 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs146779912; called by muse, mutect2, varscan2
- EIF4E | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as COSV99794917; called by muse, mutect2, varscan2
- EMX1 | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99252532; called by muse, mutect2, varscan2
- ENPP1 | c.2371G>T p.V791F | Missense Mutation (SNP) | VAF 139/361 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62933761; called by muse, mutect2, varscan2
- ETV5 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs770081575, COSV60505076; called by muse, mutect2, varscan2
- EYA4 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV62046399; called by muse, mutect2, varscan2
- FAM227B | c.51+1G>A p.X17_splice | Splice Site (SNP) | VAF 30/160 reads (19%) | catalogued as rs1187709387, COSV54810737; called by muse, mutect2, varscan2
- FAM47C | c.1901C>A p.P634H | Missense Mutation (SNP) | VAF 104/195 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63729648; called by muse, varscan2
- FMN2 | c.4600C>T p.L1534F | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60439595; called by muse, mutect2, varscan2
- GPR37 | c.1430C>G p.T477S | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV58256646; called by muse, mutect2, varscan2
- GPR55 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs757972981; called by muse, mutect2, varscan2
- GRIN2A | c.1937C>A p.T646K | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1000800098; called by muse, mutect2, varscan2
- GRXCR1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.637); catalogued as rs577521620, COSV67670049; called by muse, mutect2, varscan2
- HELZ2 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs751212065; called by muse, mutect2, varscan2
- HMCN1 | c.14775G>T p.K4925N | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs1049279757; called by muse, mutect2, varscan2
- HOXA9 | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs781090714; called by muse, varscan2
- KDM6A | c.1882G>C p.A628P | Missense Mutation (SNP) | VAF 70/111 reads (63%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.142); catalogued as rs747505929, COSV65038986, COSV65047828; called by muse, mutect2, varscan2
- KHDRBS2 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55459889, COSV55478164; called by muse, mutect2, varscan2
- KMT2D | c.16558del p.Q5520Sfs*17 | Frame Shift Del (DEL) | VAF 72/288 reads (25%) | catalogued as COSV56427597; called by mutect2, pindel, varscan2
- KRT31 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV52439080; called by muse, mutect2, varscan2
- LILRA4 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99392808; called by muse, mutect2
- LILRB2 | c.612del p.Y205Mfs*37 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as COSV58743801; called by mutect2, pindel, varscan2
- LIPH | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 99/398 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99956260; called by muse, mutect2, varscan2
- LRP1B | c.11850G>T p.R3950S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs372686162, COSV67200432; called by muse, varscan2
- LRRK2 | c.6428G>C p.R2143P | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as CM081689, COSV100111097; called by muse, mutect2, varscan2
- MAP6 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs778506126; called by muse, mutect2, varscan2
- MUC17 | c.11521G>A p.D3841N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV100072743; called by muse, mutect2, varscan2
- MYH13 | c.369T>G p.C123W | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753163138; called by muse, mutect2, varscan2
- MYO7B | c.863C>A p.S288Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs751968066; called by muse, mutect2, varscan2
- NBEAL1 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772590386; called by muse, mutect2, varscan2
- NCOA5 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 118/291 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99275261; called by muse, mutect2, varscan2
- NFIX | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 65/321 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62180163; called by muse, mutect2, varscan2
- NSMAF | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as rs367758314; called by muse, mutect2, varscan2
- NTRK3 | c.1821C>A p.C607* | Nonsense Mutation (SNP) | VAF 34/223 reads (15%) | catalogued as COSV62299204; called by muse, mutect2, varscan2
- OR10S1 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1327391703; called by muse, mutect2
- OR2T5 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 214/572 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1253903567; called by muse, varscan2
- OR5B17 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as rs562004519, COSV62160736; called by muse, mutect2, varscan2
- OR5H15 | c.644T>A p.L215H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62947835, COSV62948361; called by muse, mutect2, varscan2
- OR5T1 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); catalogued as COSV100478665; called by muse, mutect2, varscan2
- OR8B3 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 36/89 reads (40%) | catalogued as COSV63542226; called by muse, mutect2, varscan2
- OR8G1 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as rs1265187317; called by muse, mutect2, varscan2
- ORM2 | c.221C>G p.T74R | Missense Mutation (SNP) | VAF 242/418 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV99407444; called by muse, mutect2, varscan2
- PAX1 | c.589C>A p.R197S | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68271645; called by muse, mutect2, varscan2
- PDE4A | c.2510C>T p.P837L (on ENST00000380702 / NM_001111307.2; = p.P598L on NM_006202.3) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs759456652, COSV53350413; called by muse, mutect2, varscan2
- PLVAP | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53084268; called by muse, mutect2, varscan2
- POU2F1 | c.1559C>G p.T520R (on ENST00000541643 / NM_001365848.1; = p.T543R on NM_002697.4) | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs769995488; called by muse, mutect2, varscan2
- PPFIA2 | c.1943C>A p.T648K | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61031297, COSV61061302; called by muse, mutect2, varscan2
- PRAMEF1 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1201044842; called by muse, mutect2, varscan2
- PRAMEF1 | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs775750407, COSV60006481; called by mutect2, varscan2
- PTPRT | c.2632A>T p.I878F | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62016794; called by muse, mutect2, varscan2
- RIN2 | c.377A>T p.Y126F (on ENST00000255006 / NM_001242581.1; = p.Y77F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99656520; called by muse, mutect2, varscan2
- ROBO3 | c.2068T>C p.W690R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67301289; called by muse, mutect2, varscan2
- RREB1 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs776377966; called by mutect2, varscan2
- RYR1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs749591578; called by muse, mutect2, varscan2
- SELE | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as rs564943690; called by muse, mutect2, varscan2
- SEZ6L2 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as rs772158440; called by muse, mutect2, varscan2
- SHD | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs763836753; called by muse, mutect2, varscan2
- SHROOM2 | c.4267G>A p.E1423K | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs780733530, COSV66607875; called by muse, mutect2, varscan2
- SIPA1L3 | c.4898G>T p.R1633L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.643); catalogued as rs531839448; called by muse, mutect2, varscan2
- SLC6A15 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57021625; called by muse, mutect2, varscan2
- SLCO1B3 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV53937112; called by muse, mutect2, varscan2
- SPARCL1 | c.1746G>C p.K582N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56803237, COSV56804194; called by muse, mutect2, varscan2
- SQLE | c.485T>C p.I162T | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195618016; called by muse, mutect2
- SS18 | c.1201C>T p.P401S (on ENST00000415083 / NM_001007559.3; = p.P370S on NM_005637.3) | Missense Mutation (SNP) | VAF 101/205 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs1182797901; called by muse, mutect2, varscan2
- STX16 | c.157C>T p.R53C (on ENST00000371141 / NM_001001433.3; = p.R32C on NM_003763.6) | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs765221511; called by muse, mutect2, varscan2
- TBC1D10C | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408198; called by muse, mutect2, varscan2
- TBC1D9 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV71308610; called by muse, mutect2, varscan2
- TCTEX1D1 | c.156T>G p.S52R | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV99259094; called by muse, mutect2, varscan2
- TENM3 | c.7874G>T p.R2625L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69309296; called by muse, mutect2, varscan2
- TH | c.571G>T p.G191W (on ENST00000381178 / NM_199292.3; = p.G160W on NM_000360.4) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV60768370; called by muse, mutect2, varscan2
- THBD | c.1280G>T p.C427F | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1193411568; called by muse, mutect2, varscan2
- THEMIS | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs1220720885; called by muse, mutect2, varscan2
- THSD7A | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1419882431; called by muse, mutect2, varscan2
- TMTC3 | c.1688A>G p.K563R | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs763771535; called by muse, mutect2, varscan2
- TNFRSF11B | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs376517108; called by muse, mutect2, varscan2
- TP53 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52809633, COSV52992572, COSV53213865; called by muse, varscan2
- TTLL11 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs564254181; called by muse, mutect2, varscan2
- UBQLNL | c.157A>G p.R53G | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1396878281; called by muse, mutect2, varscan2
- USP11 | c.1538G>A p.R513Q (on ENST00000218348; = p.R470Q on NM_001371072.1) | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs867955965; called by muse, mutect2, varscan2
- USP29 | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54142880; called by muse, mutect2, varscan2
- VARS1 | c.2286G>C p.E762D | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV63305180; called by muse, mutect2, varscan2
- ZAN | c.4573T>C p.C1525R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427305140; called by muse, mutect2, varscan2
- ZEB2 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57962967; called by muse, mutect2, varscan2
- ZFR2 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53603445; called by muse, mutect2, varscan2
- ZNF235 | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99349167; called by muse, mutect2, varscan2
- ZNF354C | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1460849127; called by muse, mutect2
- ZNF536 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs867334103, COSV62828165, COSV62834837; called by muse, mutect2, varscan2
- ZNF648 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 110/215 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs763152829; called by muse, mutect2, varscan2
- ZNF74 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs761578174; called by muse, mutect2, varscan2
- ZP2 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as COSV99559292, COSV99559555; called by muse, mutect2, varscan2
- ZSCAN4 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as rs770095202, COSV59000222; called by muse, mutect2, varscan2
- ABCA7 | c.2888T>C p.L963P | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSM5 | c.1478A>G p.E493G | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ADGB | c.1492A>G p.I498V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ADGRD2 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- AHCYL2 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK5 | c.1210C>G p.H404D (on ENST00000354567 / NM_174858.3; = p.H378D on NM_012093.4) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ALKBH8 | c.1568A>G p.N523S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMER3 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- AMPH | c.1155G>T p.W385C | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD26 | c.3888A>T p.K1296N | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ANKRD26P1 | n.42+2T>A | Splice Site (SNP) | VAF 32/49 reads (65%) | called by muse, mutect2, varscan2
- ANKRD30A | c.1004C>A p.T335K (on ENST00000611781; = p.T279K on NM_052997.2) | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANXA6 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGAP8 | c.970+8G>T | Splice Region (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF35 | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by mutect2, varscan2
- ARMC4 | c.677C>A p.T226N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ASB10 | c.629G>C p.R210P (on ENST00000420175 / NM_001142459.2; = p.R195P on NM_080871.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.175); called by muse, varscan2
- ATP6V0A4 | c.2222A>C p.Y741S | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B2 | c.541G>T p.D181Y (on ENST00000672630; = p.D148Y on NM_001005855.2) | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIRC6 | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- BLMH | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- C17orf78 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C4orf54 | c.1530C>A p.S510R | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CATSPERG | c.3020+1G>T p.X1007_splice | Splice Site (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- CBLL1 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC40 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 49/327 reads (15%) | called by muse, mutect2, varscan2
- CDH23 | c.5870C>A p.P1957H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP72 | c.725A>T p.Q242L | Missense Mutation (SNP) | VAF 119/274 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CFAP57 | c.369G>T p.L123F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CFAP91 | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP92 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 83/397 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIPC | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CLASP1 | c.2954A>G p.D985G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2
- CLVS2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CNGB3 | c.1080G>T p.L360F | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL21A1 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL21A1 | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- COL4A2 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- CORIN | c.1965C>A p.C655* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | called by muse, varscan2
- CPEB1 | c.1512G>T p.E504D (on ENST00000617958; = p.E439D on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CRB1 | c.3880T>A p.C1294S | Missense Mutation (SNP) | VAF 185/353 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CREB3L3 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CRIP1 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CSMD1 | c.6428G>A p.C2143Y (on ENST00000520002; = p.C2142Y on NM_033225.6) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD1 | c.4126A>G p.S1376G (on ENST00000520002; = p.S1375G on NM_033225.6) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD3 | c.1073A>C p.E358A | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CTAGE9 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- CXorf66 | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 71/111 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- DAAM2 | c.1163A>T p.Y388F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); called by muse, varscan2
- DAZL | c.80C>G p.P27R | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- DES | c.659T>A p.L220Q | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH7 | c.1964G>T p.S655I | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC2LI1 | c.900G>C p.K300N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, varscan2
- EBLN1 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 48/169 reads (28%) | called by muse, mutect2, varscan2
- EBLN1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- ECH1 | c.474+4A>T | Splice Region (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- EEF1A1 | c.1231T>C p.C411R | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EFCC1 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- EID2 | c.244del p.A82Rfs*68 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- FBN3 | c.4216G>T p.D1406Y | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO43 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- FDPS | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- FMN2 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | called by muse, varscan2
- FOLH1B | n.1504G>T | Splice Region (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
- GABRB1 | c.1418T>C p.V473A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GARRE1 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- GBP4 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- GGCX | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 91/319 reads (29%) | called by muse, mutect2, varscan2
- GGCX | c.96C>G p.S32R | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GJC3 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 149/484 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLCCI1 | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- GPR155 | c.1847G>T p.S616I | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPS2 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GRID1 | c.2845A>G p.S949G | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM5 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSDMC | c.1288-1G>T p.X430_splice | Splice Site (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- GTF3C1 | c.3107del p.N1036Tfs*15 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- H1-5 | c.176_180del p.G59Vfs*6 | Frame Shift Del (DEL) | VAF 76/214 reads (36%) | called by mutect2, pindel, varscan2
- H3-3B | c.374T>A p.I125N | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HEXA | c.1119G>T p.W373C | Missense Mutation (SNP) | VAF 123/367 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLTF | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HOXA9 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.044); called by muse, varscan2
- HOXC4 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- HS1BP3 | c.471C>A p.D157E | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IBA57 | c.430A>T p.R144W | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGLV3-10 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IMPDH1 | c.859C>T p.H287Y (on ENST00000470772 / NM_001142573.2; = p.H373Y on NM_000883.4) | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- INSRR | c.774C>G p.C258W | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IQGAP1 | c.1078-1G>T p.X360_splice | Splice Site (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- IRS4 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 111/189 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ITPR2 | c.3034A>G p.S1012G | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KHDRBS2 | c.1047T>G p.Y349* | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | called by muse, varscan2
- KRTAP19-8 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LGALS16 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHX8 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.607); called by muse, mutect2
- LMOD1 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRGUK | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MBL2 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFN2 | c.2167G>T p.V723F | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MINPP1 | c.1199A>C p.H400P | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MMP14 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- MST1R | c.3461_3475del p.E1154_H1158del | In Frame Del (DEL) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- MUC22 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MYBPC1 | c.2624A>T p.K875M (on ENST00000550270 / NM_206820.2; = p.K882M on NM_002465.4) | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1E | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 100/268 reads (37%) | called by muse, mutect2, varscan2
- NAV1 | c.3644A>C p.Y1215S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.056); called by muse, mutect2
- NBEAL1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- NCF4 | c.111C>A p.S37R | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NCKAP1L | c.1338G>A p.Q446= | Splice Region (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- NCKAP5L | c.3373G>T p.G1125C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEDD1 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NEURL4 | c.2581C>G p.P861A | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NIPAL1 | c.227T>G p.V76G | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- NRCAM | c.1178G>T p.S393I (on ENST00000379028 / NM_001371124.1; = p.S387I on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- NRK | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR10K2 | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2
- OR10R2 | c.817G>C p.G273R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR52N1 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR5D13 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OR5D14 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6Q1 | c.880T>A p.Y294N | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8B2 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8D4 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OSBPL11 | c.1572G>C p.E524D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PADI2 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- PADI2 | c.355T>G p.S119A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PCDH8 | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCLO | c.10352A>G p.D3451G | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PEX13 | c.92+3G>A | Splice Region (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- PIK3R4 | c.3262A>T p.R1088* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- PKP4 | c.3198G>T p.Q1066H | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PLCH1 | c.417del p.R139Sfs*9 (on ENST00000340059 / NM_001130960.2; = p.R151Sfs*9 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 56/152 reads (37%) | called by mutect2, pindel, varscan2
- PLPP4 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPL | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- PRKD1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- PRKDC | c.5728G>T p.E1910* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- PROM2 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 68/181 reads (38%) | called by muse, mutect2, varscan2
- PRTG | c.3311C>A p.P1104H | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTBP2 | c.628del p.S210Lfs*7 (on ENST00000426398 / NM_001300986.2; = p.S202Lfs*7 on NM_021190.4) | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- PTGER3 | c.1101T>A p.Y367* | Nonsense Mutation (SNP) | VAF 26/195 reads (13%) | called by muse, mutect2, varscan2
- PTK7 | c.23dup p.A9Gfs*46 | Frame Shift Ins (INS) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- PTPA | c.556T>G p.Y186D (on ENST00000337738 / NM_178001.2; = p.Y151D on NM_021131.5) | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QKI | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- RAPGEF4 | c.2287G>T p.G763* | Nonsense Mutation (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- RASAL3 | c.1955C>G p.A652G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- RBM45 | c.518A>T p.Q173L | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- RFX2 | c.970del p.E324Nfs*15 | Frame Shift Del (DEL) | VAF 50/167 reads (30%) | called by mutect2, pindel, varscan2
- RGS22 | c.2817del p.K940Rfs*12 | Frame Shift Del (DEL) | VAF 54/228 reads (24%) | called by mutect2, pindel, varscan2
- RYR1 | c.4484G>T p.W1495L | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RYR3 | c.11464C>G p.P3822A (on ENST00000389232; = p.P3823A on NM_001036.6) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD9 | c.4394A>G p.K1465R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCG2 | c.773_776del p.E258Vfs*7 | Frame Shift Del (DEL) | VAF 35/117 reads (30%) | called by mutect2, pindel, varscan2
- SCN1A | c.1272G>T p.M424I | Missense Mutation (SNP) | VAF 63/417 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SCN2A | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCNN1D | c.1679T>G p.L560R (on ENST00000338555; = p.L724R on NM_001130413.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SEC14L4 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLECL1 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC5A4 | c.804T>A p.D268E | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SMARCAD1 | c.1886A>T p.E629V | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMARCAD1 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 100/396 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SMARCC1 | c.1460A>C p.Y487S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SP140L | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- SPRY3 | c.688del p.L230Sfs*89 | Frame Shift Del (DEL) | VAF 53/187 reads (28%) | called by mutect2, pindel, varscan2
- STRA6 | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 129/332 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- STX4 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STXBP4 | c.835T>G p.S279A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SULF1 | c.742A>G p.S248G | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2
- SYCP1 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.197); called by muse, mutect2
- TIMM10B | c.39+1_39+2del p.X13_splice | Splice Site (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel, varscan2
- TMEM145 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- TMEM163 | c.540G>C p.R180S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TMEM62 | c.1239T>A p.N413K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM8B | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMPRSS11B | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC18 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TRAF3 | c.1375T>C p.Y459H | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM26 | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM26 | c.1204G>C p.G402R | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TRIM68 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TSGA10IP | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TTN | c.44137C>A p.P14713T (on ENST00000591111; = p.P7289T on NM_003319.4) | Missense Mutation (SNP) | VAF 30/160 reads (19%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.4841G>T p.R1614M | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13D | c.4114A>T p.T1372S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- WDFY4 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- WDR64 | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZNF184 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- ZNF646 | c.4411C>G p.L1471V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF726 | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF729 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF792 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM1 | c.1395G>T p.L465= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- ACTRT2 | c.543G>A p.K181= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs758005320; called by muse, mutect2, varscan2
- ADAM29 | c.2086C>A p.R696= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- ANKRD30A | c.3717G>C p.V1239= (on ENST00000611781; = p.V1183= on NM_052997.2) | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV64623998; called by muse, mutect2, varscan2
- BCL2L15 | c.339G>T p.L113= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- BHLHE22 | c.474C>A p.L158= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- C3orf49 | c.99C>A p.G33= | Silent (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- CA10 | c.219C>A p.T73= | Silent (SNP) | VAF 34/225 reads (15%) | catalogued as rs935060725; called by muse, mutect2, varscan2
- CD22 | c.1530C>A p.V510= | Silent (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- CDH10 | c.1509A>T p.P503= | Silent (SNP) | VAF 51/141 reads (36%) | called by muse, mutect2, varscan2
- CFAP46 | c.5556C>A p.G1852= | Silent (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- CHGB | c.1230C>A p.G410= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1911C>T p.F637= | Silent (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- COL24A1 | c.1137A>G p.Q379= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- COL6A3 | c.5814A>G p.R1938= | Silent (SNP) | VAF 61/170 reads (36%) | called by muse, mutect2, varscan2
- COLEC12 | c.1152C>A p.S384= | Silent (SNP) | VAF 82/231 reads (35%) | called by muse, mutect2, varscan2
- CRAMP1 | c.2565G>T p.L855= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs199939819; called by muse, mutect2, varscan2
- DACH1 | c.1737G>A p.P579= (on ENST00000619232 / NM_001366712.1; = p.P325= on NM_004392.6) | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs370706409, COSV57512761; called by muse, mutect2, varscan2
- DDAH2 | c.480C>T p.A160= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs754239946, COSV65383756; called by muse, mutect2, varscan2
- DDX54 | c.1860C>T p.G620= | Silent (SNP) | VAF 45/137 reads (33%) | called by muse, mutect2, varscan2
- DNA2 | c.355C>T p.L119= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- DPP4 | c.1650A>T p.P550= | Silent (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- DPPA2 | c.816C>T p.G272= | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- DPYD | c.1986A>T p.A662= | Silent (SNP) | VAF 68/184 reads (37%) | called by muse, mutect2, varscan2
- DVL3 | c.489G>A p.K163= | Silent (SNP) | VAF 21/209 reads (10%) | catalogued as rs13068292; called by muse, mutect2, varscan2
- ELOA2 | c.333C>A p.G111= | Silent (SNP) | VAF 178/414 reads (43%) | catalogued as COSV99797634; called by muse, mutect2, varscan2
- ENPP1 | c.2370T>C p.G790= | Silent (SNP) | VAF 139/362 reads (38%) | catalogued as rs1201007980; called by muse, mutect2, varscan2
- FFAR1 | c.231G>T p.S77= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs375191494, COSV50049539; called by muse, mutect2, varscan2
- FSHR | c.789C>G p.A263= | Silent (SNP) | VAF 104/313 reads (33%) | called by muse, mutect2, varscan2
- FTSJ1 | c.228G>T p.L76= | Silent (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- GLB1L3 | c.891T>A p.L297= | Silent (SNP) | VAF 39/198 reads (20%) | called by muse, mutect2, varscan2
- GOLGA5 | c.1269C>A p.S423= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- H3C7 | c.354G>T p.V118= | Silent (SNP) | VAF 59/236 reads (25%) | catalogued as COSV55100329, COSV99769237; called by muse, mutect2, varscan2
- HEATR1 | c.249C>T p.T83= | Silent (SNP) | VAF 188/324 reads (58%) | catalogued as rs1411578425; called by muse, mutect2, varscan2
- HERC2 | c.12072G>C p.S4024= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV55349222; called by muse, mutect2, varscan2
- HIVEP1 | c.6678G>T p.V2226= | Silent (SNP) | VAF 77/260 reads (30%) | called by muse, mutect2, varscan2
- HRNR | c.1965A>T p.G655= | Silent (SNP) | VAF 60/808 reads (7%) | called by muse, mutect2
- IBSP | c.645A>G p.T215= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs139266884; called by muse, mutect2, varscan2
- IGFN1 | c.3708C>A p.G1236= (on ENST00000295591 / NM_001367841.1; = p.G3693= on NM_001164586.2) | Silent (SNP) | VAF 39/65 reads (60%) | called by muse, mutect2, varscan2
- ILVBL | c.411G>A p.Q137= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- INCENP | c.1659G>A p.Q553= (on ENST00000394818 / NM_001040694.2; = p.Q549= on NM_020238.3) | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs774769373; called by muse, mutect2, varscan2
- LACRT | c.45C>A p.A15= | Silent (SNP) | VAF 115/286 reads (40%) | called by muse, mutect2, varscan2
- LENG8 | c.1815G>C p.S605= | Silent (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
- LILRB2 | c.220C>A p.R74= | Silent (SNP) | VAF 159/386 reads (41%) | called by muse, mutect2, varscan2
- LRRC52 | c.744G>C p.L248= | Silent (SNP) | VAF 185/300 reads (62%) | called by muse, mutect2, varscan2
- MAP3K15 | c.177G>T p.R59= | Silent (SNP) | VAF 17/25 reads (68%) | called by muse, mutect2, varscan2
- MAP3K8 | c.1077A>G p.P359= | Silent (SNP) | VAF 56/209 reads (27%) | called by muse, mutect2, varscan2
- NARS2 | c.1044G>T p.R348= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs745628042; called by muse, mutect2, varscan2
- NDST4 | c.2527C>A p.R843= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as rs1428650595, COSV52137800; called by muse, mutect2, varscan2
- NLRP4 | c.2683T>C p.L895= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- NUP210L | c.4359G>A p.V1453= | Silent (SNP) | VAF 47/383 reads (12%) | called by muse, mutect2, varscan2
- OCA2 | c.102C>T p.G34= | Silent (SNP) | VAF 58/281 reads (21%) | called by muse, mutect2, varscan2
- OR2T12 | c.345C>A p.A115= | Silent (SNP) | VAF 79/277 reads (29%) | called by muse, varscan2
- OR51B4 | c.183G>T p.L61= | Silent (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- OR5B12 | c.288C>T p.A96= | Silent (SNP) | VAF 82/296 reads (28%) | called by muse, mutect2, varscan2
- OR5B21 | c.783C>T p.S261= | Silent (SNP) | VAF 84/219 reads (38%) | catalogued as rs1223078818; called by muse, mutect2, varscan2
- OR8B2 | c.846C>A p.P282= | Silent (SNP) | VAF 88/245 reads (36%) | catalogued as COSV100899304; called by muse, mutect2
- OR8K3 | c.78A>G p.P26= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV57132918; called by muse, mutect2, varscan2
- OTOG | c.7854C>A p.P2618= | Silent (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- PCDHA10 | c.144G>A p.A48= | Silent (SNP) | VAF 122/230 reads (53%) | catalogued as rs782508103; called by muse, mutect2, varscan2
- PCDHA9 | c.144C>T p.I48= | Silent (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.1194C>T p.N398= | Silent (SNP) | VAF 65/116 reads (56%) | called by muse, mutect2, varscan2
- PLXDC2 | c.243C>T p.S81= | Silent (SNP) | VAF 52/286 reads (18%) | catalogued as rs1171229004; called by muse, mutect2, varscan2
- PPRC1 | c.2622G>A p.S874= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs184648881; called by muse, mutect2, varscan2
- PRDM1 | c.1194C>T p.L398= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PRUNE1 | c.1062G>T p.L354= | Silent (SNP) | VAF 34/398 reads (9%) | called by muse, mutect2
- PSD3 | c.3132G>A p.K1044= (on ENST00000440756; = p.K1043= on NM_015310.4) | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs745613031; called by muse, mutect2, varscan2
- PTPRS | c.636C>A p.G212= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- RAI1 | c.2808A>G p.S936= | Silent (SNP) | VAF 93/192 reads (48%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2100C>T p.N700= | Silent (SNP) | VAF 53/85 reads (62%) | called by muse, mutect2, varscan2
- REXO1 | c.2841G>T p.P947= | Silent (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2793C>G p.L931= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV55466370; called by muse, mutect2, varscan2
- RPGR | c.1584A>T p.T528= | Silent (SNP) | VAF 54/85 reads (64%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.732A>C p.G244= | Silent (SNP) | VAF 195/338 reads (58%) | called by muse, varscan2
- RSF1 | c.3741A>C p.S1247= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2
- SGIP1 | c.147G>A p.A49= | Silent (SNP) | VAF 34/266 reads (13%) | catalogued as rs1437748168, COSV99393368; called by muse, mutect2, varscan2
- SLC25A39 | c.244C>T p.L82= (on ENST00000377095 / NM_001143780.3; = p.L74= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/179 reads (41%) | called by muse, mutect2, varscan2
- SLC39A12 | c.280C>T p.L94= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1554848379; called by muse, varscan2
- SNX15 | c.930G>T p.P310= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV57248110; called by muse, mutect2, varscan2
- SORCS3 | c.573C>A p.T191= | Silent (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- SRD5A1 | c.360G>T p.A120= | Silent (SNP) | VAF 57/227 reads (25%) | called by muse, mutect2, varscan2
- STX7 | c.282G>T p.V94= | Silent (SNP) | VAF 40/156 reads (26%) | called by muse, mutect2, varscan2
- TEX14 | c.1776G>C p.L592= (on ENST00000240361 / NM_001201457.2; = p.L586= on NM_031272.5) | Silent (SNP) | VAF 62/138 reads (45%) | called by muse, mutect2, varscan2
- TICRR | c.4962T>C p.S1654= | Silent (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- TLL1 | c.1011C>T p.I337= | Silent (SNP) | VAF 96/339 reads (28%) | catalogued as rs541355348, COSV50306345; called by muse, mutect2, varscan2
- TMC3 | c.1344T>A p.P448= | Silent (SNP) | VAF 60/283 reads (21%) | called by muse, mutect2, varscan2
- TRAF1 | c.537G>A p.Q179= | Silent (SNP) | VAF 65/106 reads (61%) | catalogued as COSV65868224; called by muse, mutect2, varscan2
- TRPM3 | c.1291C>A p.R431= (on ENST00000357533 / NM_001366142.2; = p.R276= on NM_020952.6) | Silent (SNP) | VAF 91/177 reads (51%) | catalogued as rs761235261, COSV62579679; called by muse, mutect2, varscan2
- TTN | c.47256C>A p.P15752= (on ENST00000591111; = p.P8328= on NM_003319.4) | Silent (SNP) | VAF 67/194 reads (35%) | catalogued as COSV100592212; called by muse, mutect2, varscan2
- TULP4 | c.747C>T p.I249= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- USHBP1 | c.1431G>C p.L477= | Silent (SNP) | VAF 50/185 reads (27%) | called by muse, mutect2, varscan2
- ADD3-AS1 | chr10:109942837 T>A | 3'Flank (SNP) | VAF 37/136 reads (27%) | catalogued as rs1014645991; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849342 A>C | 5'Flank (SNP) | VAF 108/174 reads (62%) | called by muse, mutect2, varscan2
- ARHGAP23P1 | chr16:33938552 G>C | 5'Flank (SNP) | VAF 14/42 reads (33%) | called by mutect2, varscan2
- ARL13B | c.*884A>T | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- BBS4 | c.77-5268G>A | Intron (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- C14orf180 | c.*25G>T | 3'UTR (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- C5orf17 | n.297G>T | RNA (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- CCDC102B | c.1263+185G>T | Intron (SNP) | VAF 19/125 reads (15%) | catalogued as rs1405487492; called by muse, mutect2, varscan2
- CEND1 | chr11:783825 G>C | 3'Flank (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- CHD5 | c.*77C>A | 3'UTR (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- DDX39B | c.616+105C>G | Intron (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.12276-20C>G | Intron (SNP) | VAF 88/164 reads (54%) | called by muse, mutect2, varscan2
- EXOSC7 | c.-25G>A | 5'UTR (SNP) | VAF 10/25 reads (40%) | catalogued as rs1054713749, COSV55557484; called by muse, mutect2, varscan2
- FAM161A | c.*1421G>T | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- FAM205BP | n.1622C>A | RNA (SNP) | VAF 71/204 reads (35%) | called by muse, mutect2, varscan2
- GNG7 | c.-38+16832A>G | Intron (SNP) | VAF 9/50 reads (18%) | catalogued as rs1411367746; called by muse, mutect2
- GNPTG | c.53-10C>A | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs564853174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GP6 | c.*883C>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- HAT1 | c.1092+38C>A | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- HAUS5 | c.-47A>G | 5'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- IGKV3-15 | c.-15G>T | 5'UTR (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- IRX5 | c.250-337C>T | Intron (SNP) | VAF 83/135 reads (61%) | called by muse, mutect2, varscan2
- KCNE4 | c.*19del | 3'UTR (DEL) | VAF 40/137 reads (29%) | called by mutect2, pindel, varscan2
- KY | c.-37G>A | 5'UTR (SNP) | VAF 77/172 reads (45%) | called by muse, mutect2, varscan2
- LILRA5 | c.-45C>A | 5'UTR (SNP) | VAF 36/79 reads (46%) | catalogued as rs768343338; called by muse, mutect2, varscan2
- LINC01387 | n.369T>A | RNA (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- LMF1 | chr16:975845 C>A | 5'Flank (SNP) | VAF 60/146 reads (41%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85805A>C | Intron (SNP) | VAF 135/410 reads (33%) | called by muse, mutect2, varscan2
- MMRN1 | c.-1G>T | 5'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- MTMR3 | c.3425+770C>T | Intron (SNP) | VAF 28/160 reads (18%) | catalogued as COSV60303590; called by muse, mutect2, varscan2
- MYBPC2 | c.-39C>A | 5'UTR (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- MYCL | c.-8del | 5'UTR (DEL) | VAF 6/48 reads (13%) | catalogued as COSV65693537; called by mutect2, varscan2
- MYL1 | c.133-1042C>G | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- MYT1 | c.1847-9C>G | Intron (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- NELFE | c.145+33A>G | Intron (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2
- NOX4 | c.153+1517C>G | Intron (SNP) | VAF 46/129 reads (36%) | catalogued as rs755928832; called by muse, mutect2, varscan2
- NTNG2 | c.1054+849G>A | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2
- PRDM5 | c.866-1369A>G | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- PRSS40A | n.142-2306G>C | Intron (SNP) | VAF 43/194 reads (22%) | called by muse, mutect2, varscan2
- PTPRK | c.495+177G>T | Intron (SNP) | VAF 35/195 reads (18%) | called by muse, mutect2, varscan2
- RABGGTB | c.4-415G>T | Intron (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- RAD51D | c.82+40C>G | Intron (SNP) | VAF 16/74 reads (22%) | catalogued as COSV104381299, COSV50100652; called by muse, mutect2, varscan2
- REXO4 | c.572+220G>A | Intron (SNP) | VAF 19/165 reads (12%) | called by muse, mutect2, varscan2
- RN7SL211P | chr2:64904493 ins A | 3'Flank (INS) | VAF 69/255 reads (27%) | called by mutect2, pindel, varscan2
- SBK3 | c.45+28A>G | Intron (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- SGCE | c.1486+45T>C | Intron (SNP) | VAF 41/103 reads (40%) | catalogued as rs756117166; called by muse, mutect2, varscan2
- SLC12A6 | c.2267+36G>T | Intron (SNP) | VAF 31/149 reads (21%) | called by muse, mutect2, varscan2
- SLC7A9 | c.1399+11A>G | Intron (SNP) | VAF 90/241 reads (37%) | catalogued as rs771232062; called by muse, mutect2, varscan2
- SMAP1 | c.118+496C>T | Intron (SNP) | VAF 59/252 reads (23%) | called by muse, mutect2, varscan2
- SSPOP | n.1169G>T | RNA (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- SSPOP | n.7254G>T | RNA (SNP) | VAF 15/65 reads (23%) | catalogued as COSV50488537; called by muse, mutect2, varscan2
- TAGLN | chr11:117207025 C>G | 3'Flank (SNP) | VAF 67/297 reads (23%) | called by muse, mutect2, varscan2
- TRPC6 | c.1128+36G>T | Intron (SNP) | VAF 60/165 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.10361-5507C>G | Intron (SNP) | VAF 25/135 reads (19%) | called by muse, mutect2, varscan2
- VPS8 | c.1782-1429A>T | Intron (SNP) | VAF 67/154 reads (44%) | called by muse, mutect2, varscan2
- VWA1 | c.-1G>A | 5'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.58-535G>T | Intron (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.*1499G>T | 3'UTR (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- ZNF971P | n.922A>C | RNA (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
